Somatic mutation profile of tumor specimen TCGA-24-1843-01A (aliquot TCGA-24-1843-01A-01W-0639-09) from TCGA case TCGA-24-1843, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.0 years (24,469 days).
Specimen TCGA-24-1843-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98e50ebf-f1ad-443f-87ec-dc8268f07c06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1843-10A (Blood Derived Normal), aliquot TCGA-24-1843-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75651d86-1a6c-4e24-8194-e9394f4bcfc9

The open-access MAF lists 91 somatic variants for this specimen: 72 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 17, Intron 2, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 55/75 reads (73%) | catalogued as rs1567541975, COSV52696505; ClinVar: pathogenic; called by muse, varscan2
- ACKR1 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as rs200287093, COSV63673147; called by muse, mutect2, varscan2
- ARHGAP36 | c.910T>C p.S304P | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52267788; called by muse, mutect2, varscan2
- ASTE1 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200808262, COSV53907523, COSV53908737; called by muse, mutect2, varscan2
- BNC1 | c.2556G>C p.E852D | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61757787; called by muse, mutect2, varscan2
- BTNL2 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs760675404, COSV66630953; called by muse, mutect2, varscan2
- CAPS2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs373505414, COSV60824815; called by muse, mutect2, varscan2
- CEP350 | c.6872A>T p.Q2291L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV62603935; called by muse, mutect2, varscan2
- CHD3 | c.1381G>C p.V461L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57875122, COSV57876247; called by muse, mutect2, varscan2
- CHD9 | c.2226C>G p.I742M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1258566652, COSV68298551; called by muse, mutect2, varscan2
- CLIP1 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV56803097; called by muse, mutect2, varscan2
- CNTNAP5 | c.1868T>A p.I623N | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV70490064; called by muse, mutect2, varscan2
- COL6A3 | c.5179C>T p.R1727W | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs143074017; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- CRYBA4 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as COSV61322140; called by muse, mutect2, varscan2
- CSMD3 | c.9763A>G p.I3255V (on ENST00000297405 / NM_001363185.1; = p.I3086V on NM_052900.3) | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV52114913, COSV52204615; called by muse, mutect2, varscan2
- DDX60L | c.2686G>T p.V896F | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52714919; called by muse, mutect2, varscan2
- DGKH | c.2805C>G p.I935M | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs751414354, COSV54933610; called by muse, mutect2, varscan2
- DISP3 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs576336989, COSV53829175, COSV99037595; called by muse, mutect2, varscan2
- DTL | c.2036G>C p.S679T | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as COSV65342553; called by muse, mutect2, varscan2
- DTX3L | c.698G>C p.S233T | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV56144484; called by muse, mutect2, varscan2
- EPB41L2 | c.953G>C p.R318P | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61356292; called by muse, mutect2, varscan2
- FAT2 | c.4210A>C p.I1404L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV55821393; called by muse, mutect2, varscan2
- FAT3 | c.11578A>C p.K3860Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV53122393; called by muse, mutect2, varscan2
- GPR137C | c.599C>A p.T200N | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.905); catalogued as COSV58705379; called by muse, mutect2, varscan2
- GPR50 | c.1767C>A p.D589E | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV99506031; called by muse, mutect2
- HECW2 | c.4460G>C p.R1487T | Missense Mutation (SNP) | VAF 104/311 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV53649803, COSV53662198; called by muse, mutect2, varscan2
- HYDIN | c.845A>G p.E282G | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55487917; called by muse, varscan2
- IPO13 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752398306, COSV64894484; called by muse, mutect2, varscan2
- ITGA2 | c.2077C>T p.Q693* | Nonsense Mutation (SNP) | VAF 41/110 reads (37%) | catalogued as COSV56860866; called by muse, mutect2, varscan2
- KIAA1755 | c.672C>A p.D224E | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs979451487, COSV54077264; called by muse, mutect2, varscan2
- KLHL11 | c.1342C>G p.L448V | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.451); catalogued as COSV100044480, COSV59862196; called by muse, mutect2, varscan2
- KRTAP10-5 | c.563G>C p.C188S | Missense Mutation (SNP) | VAF 125/683 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV59966152; called by muse, mutect2, varscan2
- LAMA1 | c.8381A>T p.D2794V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67538662; called by muse, mutect2, varscan2
- LHCGR | c.1687A>G p.K563E | Missense Mutation (SNP) | VAF 26/481 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV99683606; called by muse, mutect2
- LHFPL1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767818059, COSV64332935; called by muse, mutect2
- LHX8 | c.301T>C p.S101P | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV53957328; called by muse, mutect2, varscan2
- LMO7 | c.3420T>A p.D1140E (on ENST00000357063; = p.D821E on NM_005358.5) | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.247); catalogued as COSV58539001; called by muse, mutect2, varscan2
- LPA | c.3757C>A p.L1253I | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.124); catalogued as COSV60303345; called by muse, mutect2, varscan2
- LRRN3 | c.697G>T p.V233F | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.185); catalogued as COSV57820791; called by muse, mutect2, varscan2
- MED29 | c.166C>T p.P56S (on ENST00000615911; = p.P35S on NM_017592.4) | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs754749310, COSV55394522; called by muse, mutect2, varscan2
- MUC4 | c.13673G>A p.R4558H (on ENST00000463781 / NM_018406.7; = p.R322H on NM_004532.6) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.917); catalogued as rs756663963, COSV57765660; called by muse, mutect2
- MYO16 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs764655721, COSV51795917; called by muse, mutect2, varscan2
- NEB | c.12931G>A p.A4311T | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750215416, COSV51017285; called by muse, mutect2, varscan2
- OR2G6 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 75/395 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100598054, COSV58574350, COSV58574803; called by muse, mutect2, varscan2
- OR52E8 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 85/329 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV66207498; called by muse, mutect2, varscan2
- OR52M1 | c.368A>G p.D123G | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100798576, COSV64172135; called by muse, mutect2, varscan2
- OTOGL | c.4650C>A p.N1550K (on ENST00000547103; = p.N1541K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100087197; called by muse, mutect2, varscan2
- PCDH15 | c.4786C>T p.H1596Y (on ENST00000644397 / NM_001354429.2; = p.H1538Y on NM_001142771.2) | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as COSV100903965; called by muse, mutect2, varscan2
- PLEKHG2 | c.3352C>A p.H1118N | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.075); catalogued as COSV99217304; called by muse, mutect2
- PPP3CA | c.1195A>C p.K399Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV59924834; called by muse, mutect2, varscan2
- PRPS1L1 | c.683C>A p.T228K | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1307754739, COSV101552931; called by muse, mutect2
- ROBO1 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1375295913, COSV71395455; called by muse, mutect2, varscan2
- S1PR2 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58485491; called by muse, mutect2, varscan2
- SMCP | c.154C>G p.P52A | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.689); catalogued as COSV100908353; called by muse, mutect2
- SMOC2 | c.575G>A p.R192H (on ENST00000356284 / NM_001166412.2; = p.R203H on NM_022138.3) | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.443); catalogued as rs773020464, COSV62439207; called by muse, mutect2, varscan2
- SPAM1 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as COSV56144579; called by muse, mutect2, varscan2
- SPRR2F | c.134G>T p.C45F | Missense Mutation (SNP) | VAF 100/308 reads (32%) | PolyPhen benign (0.05); catalogued as COSV64206237; called by muse, mutect2, varscan2
- SPTA1 | c.4186G>A p.E1396K | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV63754613; called by muse, mutect2, varscan2
- SPTLC3 | c.1039A>T p.T347S | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.14); catalogued as COSV65466225; called by muse, mutect2, varscan2
- TCP11L2 | c.41A>T p.Q14L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.397); catalogued as COSV54430595; called by muse, mutect2, varscan2
- TINAG | c.863G>C p.S288T | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.519); catalogued as COSV99449437; called by muse, mutect2, varscan2
- TLR1 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 77/362 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs750892111, COSV58303872; called by muse, mutect2, varscan2
- TLR1 | c.53G>T p.R18I | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV58304623; called by muse, mutect2, varscan2
- TMEM52B | c.42del p.Y15Ifs*21 (on ENST00000381923 / NM_001079815.1; = p.C9Lfs*7 on NM_153022.4) | Frame Shift Del (DEL) | VAF 73/281 reads (26%) | catalogued as COSV53728643; called by mutect2, pindel, varscan2
- TRAV8-3 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs1458088580; called by muse, mutect2
- TRHDE | c.2180T>A p.L727Q | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53848117; called by muse, mutect2, varscan2
- UROD | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55800711; called by muse, mutect2, varscan2
- VPS13A | c.8554-2A>G p.X2852_splice | Splice Site (SNP) | VAF 47/154 reads (31%) | catalogued as COSV62431412; called by muse, mutect2, varscan2
- WNT16 | c.500dup p.C168Lfs*4 (on ENST00000222462 / NM_057168.2; = p.C158Lfs*4 on NM_016087.2) | Frame Shift Ins (INS) | VAF 10/60 reads (17%) | catalogued as rs771899177; called by mutect2, varscan2
- ZNF479 | c.828A>T p.Q276H | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV58639460; called by muse, mutect2, varscan2
- KDM5C | c.4436del p.P1479Qfs*65 | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | called by mutect2, pindel, varscan2
- TACC2 | c.1919dup p.A641Cfs*15 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by pindel, varscan2
- BACH2 | c.1584C>T p.Y528= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as rs761668194, COSV57595357; called by muse, mutect2, varscan2
- DNAH8 | c.12114G>C p.L4038= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as COSV59452886; called by muse, mutect2, varscan2
- ITIH6 | c.1203G>A p.T401= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs777148282, COSV54488381; called by muse, mutect2, varscan2
- OR8A1 | c.453C>A p.I151= | Silent (SNP) | VAF 63/207 reads (30%) | catalogued as COSV52508967; called by muse, mutect2, varscan2
- PCDH15 | c.4785C>A p.I1595= (on ENST00000644397 / NM_001354429.2; = p.I1537= on NM_001142771.2) | Silent (SNP) | VAF 51/199 reads (26%) | catalogued as rs1406042709, COSV64672125; called by muse, mutect2, varscan2
- PCDHA13 | c.1443C>T p.D481= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs1554179442, COSV56500898; called by muse, mutect2, varscan2
- PCDHB2 | c.330G>A p.V110= | Silent (SNP) | VAF 4/83 reads (5%) | catalogued as COSV99523091; called by muse, mutect2
- PSMF1 | c.735C>A p.P245= | Silent (SNP) | VAF 39/157 reads (25%) | catalogued as COSV55674368, COSV55674767; called by muse, mutect2, varscan2
- SLITRK4 | c.1143G>A p.K381= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as COSV62024329, COSV62025392; called by muse, mutect2, varscan2
- SLITRK5 | c.2829G>C p.P943= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV61522231, COSV61523393; called by muse, mutect2, varscan2
- SPAG5 | c.2046G>T p.V682= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV58802179; called by muse, mutect2, varscan2
- SSRP1 | c.2112G>A p.A704= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs564469054, COSV53479904; called by muse, mutect2, varscan2
- TAS1R2 | c.102C>A p.L34= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV64745404; called by muse, mutect2, varscan2
- TFRC | c.2067C>T p.Y689= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs199652297, COSV64055057; called by muse, mutect2, varscan2
- TM4SF1 | c.375C>T p.L125= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs147261725; called by muse, mutect2, varscan2
- USH2A | c.11637G>T p.G3879= | Silent (SNP) | VAF 46/217 reads (21%) | catalogued as COSV56382174; called by muse, mutect2, varscan2
- ZFP14 | c.231C>T p.C77= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs1171759804, COSV54202812; called by muse, mutect2, varscan2
- TTN | c.10361-5297G>C | Intron (SNP) | VAF 40/185 reads (22%) | catalogued as COSV60117829, COSV60311184; called by muse, mutect2, varscan2
- TTN | c.10303+2597G>A | Intron (SNP) | VAF 5/106 reads (5%) | catalogued as COSV100610179, COSV100616365; called by muse, mutect2
